CCDI case PBCEHX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thymus.
https://portal.gdc.cancer.gov/cases/08514fd3-46c8-4b8e-9082-1348caf9b0c0

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Thymoma, NOS: ICD-O-3 morphology code: 8580/3; Tissue or organ of origin: Thymus; Age at diagnosis: 14.7 years (5,373 days).

Biospecimens (3 samples)
- Sample 0DPYD8: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DPYDY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPYE5: Tissue type: Tumor; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
